TCGA case TCGA-29-1711 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f58e49fc-9641-4b46-be4c-766445ec70a3

Demographics
Sex at birth: female; Race: black or african american; Age at index: 45 years; Vital status: Alive.

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 45.1 years (16,485 days); Year of diagnosis: 2006; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G2; Prior treatment: No; Days to last follow up: 1,053 days (2.9 years).
   Pathology details: Residual tumor measurement: No macroscopic disease.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Days to treatment start: 30 days; Days to treatment end: 234 days; Treatment dose: 1,863 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Treatment intent type: Adjuvant; Days to treatment start: 30 days; Days to treatment end: 136 days; Number of cycles: 6; Treatment dose: 150 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 30 days; Days to treatment end: 136 days; Number of cycles: 6; Treatment dose: 170 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 1,053 days (2.9 years); Disease response: Tumor Free.
- ECOG performance status: 0; Timepoint: Post Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-29-1711-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 1.1; Shortest dimension: 0.4.
  Slide TCGA-29-1711-01A-01-TS1: Section location: Top; Percent tumor cells: 98; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 0.
  Slide TCGA-29-1711-01A-01-BS1: Section location: Bottom; Percent tumor cells: 98; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 3.
- Sample TCGA-29-1711-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: Tumor free; History neoadjuvant treatment: No; Performance status timing: Post-Adjuvant Therapy; Method initial path diagnosis: Tumor resection.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,053 days; disease-specific survival: no event (censored), 1,053 days; disease-free interval: no event (censored), 1,053 days; progression-free interval: no event (censored), 1,053 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-29-1711-01A-01D-0559-01): tumor purity 0.84, ploidy 1.93, whole-genome doublings 0.
